Somatic mutation profile of tumor specimen TCGA-CK-5914-01A (aliquot TCGA-CK-5914-01A-11D-1650-10) from TCGA case TCGA-CK-5914, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 81.0 years (29,586 days).
Specimen TCGA-CK-5914-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe709944-9f90-4013-b8a3-aa07989e391c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CK-5914-10A (Blood Derived Normal), aliquot TCGA-CK-5914-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/369bd88b-6411-4030-a908-9277df37c67d

The open-access MAF lists 147 somatic variants for this specimen: 113 protein-altering or splice-affecting, 30 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 100, Silent 30, Nonsense Mutation 6, Frame Shift Del 2, In Frame Del 2, Frame Shift Ins 1, 3'UTR 1, RNA 1, Splice Region 1, 5'UTR 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 108/207 reads (52%) | hotspot (GDC flag); catalogued as rs62619935, CM992133, COSV57320867; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL6A2 | c.2488C>T p.R830W | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373072443, CM098044; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 58/84 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ADAM8 | c.1460C>T p.P487L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373192234, COSV101291695; called by muse, mutect2, varscan2
- ADAMTS2 | c.2071C>T p.R691C | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs753921602, COSV52379230; called by muse, mutect2, varscan2
- ADGRL2 | c.4196G>C p.R1399T (on ENST00000370717 / NM_001366005.1; = p.R1343T on NM_012302.4) | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.263); catalogued as COSV54672579; called by muse, mutect2
- APC | c.7078G>A p.G2360S | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT tolerated (0.28); PolyPhen benign (0.054); catalogued as COSV99967740; called by muse, mutect2, varscan2
- ARID3A | c.1093G>A p.G365R | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as rs538606329, COSV55044793; called by muse, varscan2
- BACE1 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.569); catalogued as rs138138981; called by muse, mutect2, varscan2
- C10orf90 | c.1952G>A p.R651Q | Missense Mutation (SNP) | VAF 66/219 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747778520, COSV52957281; called by muse, mutect2, varscan2
- C10orf90 | c.758A>T p.H253L | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV52957293; called by muse, mutect2, varscan2
- CAPS2 | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 101/186 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs764447136, COSV60826315; called by muse, mutect2, varscan2
- CCDC124 | c.187C>T p.Q63* | Nonsense Mutation (SNP) | VAF 19/51 reads (37%) | catalogued as COSV71490426; called by muse, mutect2, varscan2
- CCDC172 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as rs748847947, COSV60938304; called by muse, mutect2, varscan2
- CCDC88B | c.3379C>T p.R1127W | Missense Mutation (SNP) | VAF 63/121 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs146372637; called by muse, mutect2, varscan2
- CCN5 | c.310G>A p.G104S | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51937676; called by muse, mutect2, varscan2
- CDK13 | c.2456G>C p.R819T | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV51701715; called by muse, mutect2, varscan2
- CECR2 | c.1699C>T p.R567* (on ENST00000342247 / NM_001290047.2; = p.R384* on NM_001290046.1) | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as COSV99377879; called by muse, mutect2, varscan2
- CMKLR1 | c.898C>A p.L300M (on ENST00000312143 / NM_001142344.2; = p.L298M on NM_004072.3) | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV56439057; called by muse, mutect2, varscan2
- CNTNAP2 | c.260T>A p.V87D | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100666344; called by muse, mutect2, varscan2
- COL6A3 | c.3457G>A p.V1153M | Missense Mutation (SNP) | VAF 63/103 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as rs767960391, COSV99798138; called by muse, mutect2, varscan2
- COL6A6 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.538); catalogued as rs368728937; called by muse, mutect2, varscan2
- COL7A1 | c.3602G>A p.R1201H | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs189206728, COSV60396684; called by muse, mutect2, varscan2
- CYLC2 | c.329A>C p.K110T | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as COSV66337989; called by muse, mutect2, varscan2
- DHPS | c.931G>T p.E311* | Nonsense Mutation (SNP) | VAF 13/24 reads (54%) | catalogued as COSV52951690, COSV52952356; called by muse, mutect2, varscan2
- DNM2 | c.1255A>C p.K419Q | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as COSV100117218; called by muse, mutect2, varscan2
- DYTN | c.1127G>A p.R376K | Missense Mutation (SNP) | VAF 345/534 reads (65%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757571480, COSV71752298; called by muse, mutect2, varscan2
- ERICH3 | c.3754G>A p.A1252T | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs151238210, COSV58609761; called by muse, mutect2, varscan2
- ERICH3 | c.2902G>A p.D968N | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.056); catalogued as rs757366339, COSV58605808; called by muse, mutect2, varscan2
- FCN1 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs375520544, COSV65662578; called by muse, mutect2, varscan2
- FEM1A | c.1111C>T p.R371C | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774638617, COSV54163770; called by mutect2, varscan2
- FGF12 | c.494G>A p.R165H (on ENST00000454309 / NM_021032.5; = p.R103H on NM_004113.6) | Missense Mutation (SNP) | VAF 43/225 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs768509717, COSV53170653; called by muse, mutect2, varscan2
- GLRB | c.213A>G p.I71M | Missense Mutation (SNP) | VAF 115/230 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.29); catalogued as COSV52414768; called by muse, mutect2, varscan2
- HIVEP3 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs377429669, COSV56017131; called by muse, mutect2, varscan2
- IKZF1 | c.928G>A p.V310M | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.998); catalogued as COSV58780321, COSV58787367; called by muse, mutect2, varscan2
- IKZF4 | c.1483G>A p.A495T | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.897); catalogued as rs201396607; called by muse, mutect2, varscan2
- IVL | c.998T>G p.L333R | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.86); PolyPhen benign (0.223); catalogued as COSV100908160; called by muse, mutect2
- KIAA1217 | c.428C>A p.T143K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV100907963, COSV100908429; called by muse, mutect2
- KRTAP27-1 | c.39C>A p.H13Q | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV67001824; called by muse, mutect2, varscan2
- LIN7A | c.280G>A p.V94I | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.255); catalogued as COSV99692102; called by muse, mutect2, varscan2
- LORICRIN | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 25/87 reads (29%) | PolyPhen probably damaging (0.998); catalogued as rs1291098844, COSV64201514; called by muse, mutect2, varscan2
- MAP1LC3A | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 27/337 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs753652508, COSV54163573; called by muse, mutect2
- MC3R | c.930T>G p.F310L | Missense Mutation (SNP) | VAF 32/400 reads (8%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.97); catalogued as COSV54764063; called by muse, mutect2
- MED16 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs759087690, COSV54127508; called by muse, mutect2, varscan2
- MGARP | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs368177178, COSV67449457; called by muse, mutect2, varscan2
- NALCN | c.3685G>T p.V1229F | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.214); catalogued as rs369352209; called by muse, mutect2, varscan2
- NDOR1 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); catalogued as rs747559988, COSV61288504; called by muse, mutect2, varscan2
- NDST4 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as rs765437158, COSV52109844, COSV52125800; called by muse, mutect2, varscan2
- NGLY1 | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.232); catalogued as rs142766875; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NHLRC3 | c.741G>T p.W247C | Missense Mutation (SNP) | VAF 34/305 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV65463020; called by muse, mutect2, varscan2
- NKX6-2 | c.614A>T p.K205M | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63973805; called by muse, mutect2, varscan2
- NOS1 | c.1714G>A p.V572M | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1412760885, COSV57606502; called by muse, mutect2, varscan2
- NPY2R | c.457G>A p.V153I | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.087); catalogued as rs146320853; called by muse, mutect2, varscan2
- NUDT6 | c.427C>G p.Q143E | Missense Mutation (SNP) | VAF 123/213 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs1472850469, COSV58646528; called by muse, varscan2
- NUDT6 | c.329C>A p.S110Y | Missense Mutation (SNP) | VAF 114/222 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV100193743, COSV58646826; called by muse, varscan2
- OR1L4 | c.587G>T p.S196I | Missense Mutation (SNP) | VAF 210/768 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.529); catalogued as COSV52340712; called by muse, varscan2
- OR8D1 | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.023); catalogued as COSV63442507; called by muse, mutect2, varscan2
- PABPC4 | c.961A>G p.T321A | Missense Mutation (SNP) | VAF 77/116 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63293481; called by muse, mutect2, varscan2
- PALM | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV52768252, COSV99214501; called by muse, mutect2, varscan2
- PCDHA4 | c.414G>C p.K138N | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.889); catalogued as COSV100793543, COSV63540086, COSV63542776; called by muse, mutect2, varscan2
- PCDHA8 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 83/164 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); catalogued as rs200720426, COSV65323235; called by muse, mutect2, varscan2
- PCDHA9 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.089); catalogued as rs1554143525, COSV65327085; called by muse, mutect2, varscan2
- PIK3R1 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99143481; called by muse, mutect2, varscan2
- PNMA8A | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as COSV58137512; called by muse, mutect2, varscan2
- POLRMT | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs751184321, COSV73933318; called by muse, mutect2, varscan2
- PRPF31 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV58086760; called by muse, mutect2, varscan2
- PTPN3 | c.1068A>T p.R356S | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV52707045; called by muse, mutect2, varscan2
- PTPRN2 | c.1678G>A p.A560T | Missense Mutation (SNP) | VAF 44/237 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.255); catalogued as rs201100433; called by muse, mutect2, varscan2
- QRICH2 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762004308, COSV99428981; called by muse, mutect2, varscan2
- RAPH1 | c.2570C>T p.P857L | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.67); catalogued as rs374443910; called by muse, mutect2, varscan2
- RFTN1 | c.1553A>C p.E518A | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.059); catalogued as COSV61920183; called by muse, mutect2, varscan2
- RNF213 | c.13780G>A p.A4594T | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.612); catalogued as rs1409930294, COSV100300529; called by muse, mutect2, varscan2
- ROBO4 | c.620G>T p.C207F | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60625136; called by muse, mutect2, varscan2
- ROR2 | c.233C>T p.T78M | Missense Mutation (SNP) | VAF 87/200 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs369545969; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPL18A | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV99714410; called by muse, mutect2, varscan2
- RPS6KA2 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 50/59 reads (85%) | SIFT tolerated (0.06); PolyPhen benign (0.284); catalogued as rs367918929; called by muse, mutect2, varscan2
- RTEL1 | c.1595+2T>A p.X532_splice | Splice Site (SNP) | VAF 9/147 reads (6%) | catalogued as COSV100542224; called by muse, mutect2
- SAGE1 | c.1709G>T p.S570I | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as COSV61017891; called by muse, mutect2, varscan2
- SDK1 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 68/141 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs376569849; called by muse, mutect2, varscan2
- SEZ6L | c.2248G>A p.E750K | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766461805, COSV50667975; called by muse, mutect2, varscan2
- SGCG | c.751A>G p.T251A | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs201535503, COSV99522890; called by muse, mutect2, varscan2
- SLC17A8 | c.411C>G p.F137L | Missense Mutation (SNP) | VAF 78/262 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as COSV100035013, COSV60124548; called by muse, mutect2, varscan2
- SLC23A3 | c.125C>A p.S42Y | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); catalogued as COSV55406839, COSV55407985; called by muse, mutect2, varscan2
- SLC29A4 | c.50C>T p.T17I | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as COSV51874767; called by muse, mutect2, varscan2
- SLC37A2 | c.361G>T p.G121* | Nonsense Mutation (SNP) | VAF 52/222 reads (23%) | catalogued as COSV100017211; called by muse, mutect2, varscan2
- SLC9A8 | c.767C>T p.T256I | Missense Mutation (SNP) | VAF 44/518 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV64289109; called by muse, mutect2
- SMURF1 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs775470035, COSV63155644; called by muse, mutect2, varscan2
- SPAG17 | c.4514G>C p.C1505S | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100309130, COSV60461086; called by muse, mutect2, varscan2
- SPG7 | c.1150C>T p.R384W (on ENST00000268704; = p.R391W on NM_003119.4) | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057524520, COSV51953294; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TBX20 | c.1218G>T p.M406I | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.48); catalogued as COSV68784100; called by muse, mutect2, varscan2
- TEX14 | c.3842G>T p.R1281I (on ENST00000240361 / NM_001201457.2; = p.R1235I on NM_031272.5) | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as COSV99542187; called by muse, mutect2, varscan2
- THYN1 | c.387C>T p.I129= | Splice Region (SNP) | VAF 126/490 reads (26%) | catalogued as rs148055755, COSV55542002; called by muse, varscan2
- TMEM214 | c.411C>A p.N137K | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV99476257; called by muse, mutect2, varscan2
- TMEM9 | c.520A>G p.T174A | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs776119463, COSV100947376; called by muse, mutect2, varscan2
- TNPO1 | c.2462C>T p.A821V | Missense Mutation (SNP) | VAF 106/411 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV61522258; called by muse, mutect2, varscan2
- TNRC6A | c.500A>C p.K167T | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.461); catalogued as COSV59366349; called by muse, mutect2
- TRAPPC9 | c.3287C>T p.P1096L | Missense Mutation (SNP) | VAF 35/52 reads (67%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs991466060, COSV66902047; called by muse, mutect2, varscan2
- TRMT12 | c.487A>G p.T163A | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV60777277; called by muse, mutect2, varscan2
- TTC4 | c.251A>G p.D84G | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV100988420; called by muse, mutect2, varscan2
- TTN | c.30440G>A p.R10147Q (on ENST00000591111; = p.R9220Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 166/382 reads (43%) | PolyPhen probably damaging (0.986); catalogued as rs727504757, COSV100611691; ClinVar: uncertain significance; called by muse, varscan2
- UNC45B | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.194); catalogued as rs767929982, COSV52096913; called by muse, mutect2, varscan2
- WASF3 | c.165G>T p.L55F | Missense Mutation (SNP) | VAF 21/175 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58967393; called by muse, mutect2, varscan2
- ZNF423 | c.2276G>A p.R759H (on ENST00000563137 / NM_001379286.1; = p.R751H on NM_015069.4) | Missense Mutation (SNP) | VAF 69/133 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as rs143285873; called by muse, mutect2, varscan2
- ZNF45 | c.263C>T p.T88I | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV54193447; called by muse, mutect2, varscan2
- ZNF804B | c.688A>T p.K230* | Nonsense Mutation (SNP) | VAF 28/158 reads (18%) | catalogued as COSV60832655; called by muse, mutect2, varscan2
- ZNF804B | c.1085A>G p.Q362R | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV60832663; called by muse, mutect2
- ANKRD20A1 | c.775C>G p.L259V | Missense Mutation (SNP) | VAF 466/1368 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.117); called by mutect2, varscan2
- GIN1 | c.581_586del p.F194_L195del | In Frame Del (DEL) | VAF 57/234 reads (24%) | called by mutect2, pindel, varscan2
- GPR156 | c.790del p.V264Sfs*13 | Frame Shift Del (DEL) | VAF 26/64 reads (41%) | called by mutect2, pindel, varscan2
- H4C11 | c.117_120del p.R40Afs*4 | Frame Shift Del (DEL) | VAF 60/70 reads (86%) | called by mutect2, varscan2
- PXDN | c.3951_3952dup p.D1318Efs*87 | Frame Shift Ins (INS) | VAF 5/31 reads (16%) | called by mutect2, pindel
- SPRED1 | c.1192_1194del p.D398del | In Frame Del (DEL) | VAF 56/228 reads (25%) | called by pindel, varscan2
- TPTE | c.1207C>A p.L403I (on ENST00000618007 / NM_199261.4; = p.L385I on NM_199259.4) | Missense Mutation (SNP) | VAF 74/734 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BBS10 | c.465T>C p.S155= | Silent (SNP) | VAF 52/101 reads (51%) | catalogued as COSV53884265; called by muse, mutect2, varscan2
- BEGAIN | c.951G>A p.T317= | Silent (SNP) | VAF 46/98 reads (47%) | catalogued as rs368095998; called by muse, mutect2, varscan2
- CACNA1G | c.2148G>T p.L716= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV100661762; called by muse, mutect2, varscan2
- CCNA1 | c.1218A>G p.E406= | Silent (SNP) | VAF 40/318 reads (13%) | catalogued as COSV55222185; called by muse, mutect2, varscan2
- COL3A1 | c.2958C>T p.N986= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as rs41264441; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- DCSTAMP | c.1254A>G p.Q418= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as COSV52578305; called by muse, mutect2, varscan2
- DCUN1D5 | c.348C>T p.D116= | Silent (SNP) | VAF 86/155 reads (55%) | catalogued as COSV52784767; called by muse, mutect2, varscan2
- DIAPH3 | c.1845C>T p.P615= (on ENST00000400324 / NM_001042517.2; = p.P352= on NM_030932.3) | Silent (SNP) | VAF 44/324 reads (14%) | catalogued as COSV57372321; called by muse, mutect2, varscan2
- DNMBP | c.1131C>T p.D377= | Silent (SNP) | VAF 28/126 reads (22%) | catalogued as rs560503880, COSV100143717, COSV60627410; called by muse, mutect2, varscan2
- ELAVL2 | c.78G>A p.S26= | Silent (SNP) | VAF 233/572 reads (41%) | catalogued as rs1453909653, COSV56359418; called by muse, mutect2, varscan2
- FAM83H | c.1347C>T p.H449= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV66354021; called by muse, mutect2, varscan2
- FOXL1 | c.888G>A p.S296= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV57214526; called by muse, mutect2, varscan2
- FSHR | c.255G>T p.V85= | Silent (SNP) | VAF 82/372 reads (22%) | catalogued as COSV58624524; called by muse, mutect2, varscan2
- GRIK2 | c.1653C>T p.G551= | Silent (SNP) | VAF 459/540 reads (85%) | catalogued as rs746635578, COSV59743529, COSV59750731; called by muse, mutect2, varscan2
- HOXB5 | c.501C>T p.A167= | Silent (SNP) | VAF 31/99 reads (31%) | catalogued as COSV53313412; called by muse, mutect2, varscan2
- HOXC13 | c.837C>T p.Y279= | Silent (SNP) | VAF 44/84 reads (52%) | catalogued as rs747370796, COSV54499101; called by muse, mutect2, varscan2
- ITFG1 | c.450C>T p.L150= | Silent (SNP) | VAF 97/513 reads (19%) | catalogued as rs1296205841, COSV57750222; called by muse, mutect2, varscan2
- MCM3AP | c.3243G>A p.A1081= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as rs778113579, COSV52436872, COSV52440125; called by muse, mutect2, varscan2
- MTMR1 | c.1114T>C p.L372= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as COSV64892584; called by muse, mutect2, varscan2
- NALCN | c.2790C>T p.S930= | Silent (SNP) | VAF 92/240 reads (38%) | catalogued as COSV51942573; called by muse, mutect2, varscan2
- NBEA | c.4389T>A p.S1463= | Silent (SNP) | VAF 39/324 reads (12%) | catalogued as COSV59793662; called by muse, mutect2, varscan2
- NOL11 | c.1494A>G p.E498= | Silent (SNP) | VAF 41/144 reads (28%) | catalogued as COSV99475051; called by muse, mutect2, varscan2
- PCDHGB2 | c.855C>T p.D285= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as rs1486053605, COSV53894909; called by muse, mutect2, varscan2
- PCDHGB3 | c.363G>C p.V121= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as COSV53967457; called by muse, mutect2, varscan2
- QRICH1 | c.1443A>G p.V481= | Silent (SNP) | VAF 108/205 reads (53%) | catalogued as rs781160612, COSV62616128; called by muse, mutect2, varscan2
- SOX21 | c.90C>T p.N30= | Silent (SNP) | VAF 51/462 reads (11%) | catalogued as rs939243334, COSV65375365; called by muse, mutect2, varscan2
- TECTA | c.3039C>T p.C1013= | Silent (SNP) | VAF 67/117 reads (57%) | catalogued as COSV50724516; called by muse, mutect2, varscan2
- TGFBR2 | c.927G>A p.T309= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs756625146, COSV55451672, COSV55458639; ClinVar: likely benign; called by muse, mutect2, varscan2
- TRHDE | c.714C>T p.N238= | Silent (SNP) | VAF 17/27 reads (63%) | catalogued as COSV53849162; called by muse, mutect2, varscan2
- ZAP70 | c.441G>A p.P147= | Silent (SNP) | VAF 46/79 reads (58%) | catalogued as rs1309520748, COSV53854979; called by muse, mutect2, varscan2
- C16orf90 | c.71+30A>G | Intron (SNP) | VAF 17/73 reads (23%) | catalogued as COSV68714512; called by muse, mutect2, varscan2
- GABRG2 | c.*2G>A | 3'UTR (SNP) | VAF 94/327 reads (29%) | catalogued as COSV100729684; called by muse, mutect2, varscan2
- STAG3L2 | n.737G>A | RNA (SNP) | VAF 67/328 reads (20%) | called by muse, mutect2, varscan2
- ZFYVE19 | c.-2G>T | 5'UTR (SNP) | VAF 14/48 reads (29%) | catalogued as COSV99591663; called by muse, mutect2, varscan2
